Gene-level copy-number profile of tumor specimen TCGA-JW-A5VI-01A from TCGA case TCGA-JW-A5VI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 45.0 years (16,444 days).
Specimen TCGA-JW-A5VI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.973894f5-c3ef-487d-8ee7-e8b0115c0839.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JW-A5VI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/80df57e2-6b1c-4c55-8849-673bd56a2e20

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,896; copy number 2: 45,857; copy number 3: 2,301; copy number 4: 1,425; copy number 5: 106; copy number 7: 93; copy number 8: 138.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JW-A5VI-01A-11D-A28A-01): tumor purity 0.67, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 337 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:34,430,880–36,697,867, 45 genes, copy number 7: CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1.
- chr17:20,595,531–21,594,180, 48 genes, copy number 7: AC087499.3, AC087499.1, AC087499.4, LINC02088, AC087499.7, AC087499.5, AC087499.6, AC087499.2, RNFT1P3, HNRNPA1P19, OLA1P2, SCDP1, AC126365.1, AC126365.2, ABHD17AP6, CCDC144NL, AC090774.2, CCDC144NL-AS1, RNU6-1178P, RNASEH1P1, AC090774.1, SPECC1P2, AC107926.1, AC087393.3, AC087393.1, USP22, AC087393.2, LINC01563, DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2.
- chr19:39,083,913–39,934,626, 54 genes, copy number 5: ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP.
- chr19:41,301,587–42,855,691, 82 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr19:43,211,791–45,092,635, 105 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr19:45,091,396–45,148,077, 3 genes, copy number 5: PPP1R37, EIF5AP3, AC005757.1.

Autosomal genes at a single copy (total copy number 1): 9,573. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
